Gene-level copy-number profile of tumor specimen TCGA-IR-A3LL-01A from TCGA case TCGA-IR-A3LL, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB1; Tumor grade: G2; Age at diagnosis: 60.6 years (22,123 days).
Specimen TCGA-IR-A3LL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-CESC.70d9c94b-3472-4005-bb37-71965c1746c7.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-IR-A3LL-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/66b7e413-5015-4ede-8495-280262059615

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 21; copy number 1: 23; copy number 2: 1,269; copy number 4: 36,644; copy number 5: 822; copy number 6: 17,755; copy number 7: 1,512; copy number 8: 1,773.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-IR-A3LL-01A-11D-A20T-01): tumor purity 0.5, ploidy 2.4, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 21 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:26,481,396–27,282,225, 10 genes (within-gene range 0–4): CCKAR, TBC1D19, AC107390.1, STIM2, STIM2-AS1, PIMREGP4, AC024132.2, AC024132.1, LINC02261, Y_RNA.
- chr10:87,994,618–88,584,530, 4 genes (within-gene range 0–6): AC063965.1, MED6P1, AL353149.1, RNLS.
- chr11:128,965,060–129,279,324, 1 gene (within-gene range 0–2): ARHGAP32.
- chr11:129,202,966–129,617,269, 6 genes: RNU6-874P, ZNF123P, BARX2, RPS27P20, AP003500.1, LINC01395.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 23. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
